MMRF case MMRF_1825 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/0c052aa2-6f65-4c07-b319-41e7d520ac57

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 54 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 55.0 years (20,074 days); ISS stage: II; Days to last known disease status: 1,088 days (3.0 years); Days to last follow up: 1,088 days (3.0 years).
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 2 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 196 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 927 days (2.5 years).
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 8 days; Days to treatment end: 196 days.
   Treatment given: Therapeutic agents: Dexamethasone + Other; Regimen or line of therapy: First line of therapy; Days to treatment start: 197 days; Days to treatment end: 287 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 197 days; Days to treatment end: 257 days.
   Treatment given: Therapeutic agents: Dexamethasone + Elotuzumab + Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 889 days (2.4 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1 (ECOG 1): M Protein 4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.44 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 42.7 mg/dL; Immunoglobulin G 59.9 g/L; Immunoglobulin A 0.18 g/L; Immunoglobulin M 0.3 g/L; Beta 2 Microglobulin 4.6 µg/mL; Lactate Dehydrogenase 2 µkat/L; Hemoglobin 6.32 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 291 ×10⁹/L; Creatinine 103 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.28 mmol/L; Albumin 32 g/L; Total Protein 9.6 g/dL; Glucose 5.89 mmol/L; C-Reactive Protein 12.8 mg/dL.
- Day 92 (ECOG 1): M Protein 0.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.09 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.41 mg/dL; Immunoglobulin G 10.6 g/L; Immunoglobulin A 0.16 g/L; Immunoglobulin M 0.25 g/L; Lactate Dehydrogenase 3.5 µkat/L; Hemoglobin 7.25 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 165 ×10⁹/L; Creatinine 110 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.38 mmol/L; Albumin 41 g/L; Total Protein 6.2 g/dL; Glucose 5.06 mmol/L.
- Day 183 (ECOG 1): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.04 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.79 mg/dL; Immunoglobulin G 7.41 g/L; Immunoglobulin A 0.16 g/L; Immunoglobulin M 0.34 g/L; Lactate Dehydrogenase 3.68 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 3.9 ×10⁹/L; Platelets 183 ×10⁹/L; Creatinine 126 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.4 mmol/L; Albumin 44 g/L; Total Protein 6.6 g/dL; Glucose 5.45 mmol/L.
- Day 260 (ECOG 1): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.04 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.79 mg/dL; Immunoglobulin G 5.12 g/L; Immunoglobulin A 0.18 g/L; Immunoglobulin M 0.26 g/L; Lactate Dehydrogenase 4.05 µkat/L; Hemoglobin 9.24 mmol/L; Leukocytes 7.7 ×10⁹/L; Absolute Neutrophil 6.8 ×10⁹/L; Platelets 194 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.43 mmol/L; Albumin 41 g/L; Total Protein 6.1 g/dL; Glucose 6.33 mmol/L.
- Day 372 (ECOG 1): M Protein 0.05 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.74 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.61 mg/dL; Immunoglobulin G 9.94 g/L; Immunoglobulin A 1.03 g/L; Immunoglobulin M 0.34 g/L; Lactate Dehydrogenase 2.47 µkat/L; Hemoglobin 8.62 mmol/L; Leukocytes 6.2 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 231 ×10⁹/L; Creatinine 84 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.4 mmol/L; Albumin 41 g/L; Total Protein 6.5 g/dL; Glucose 4.95 mmol/L.
- Day 456: M Protein 0.05 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.89 mg/dL; Immunoglobulin G 13.1 g/L; Immunoglobulin A 1.78 g/L; Immunoglobulin M 0.27 g/L; Lactate Dehydrogenase 2.15 µkat/L; Hemoglobin 8.12 mmol/L; Leukocytes 5.9 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 169 ×10⁹/L; Creatinine 102 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.25 mmol/L; Albumin 38 g/L; Total Protein 6.4 g/dL; Glucose 4.57 mmol/L.
- Day 541 (ECOG 1): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.18 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.73 mg/dL; Immunoglobulin G 12.3 g/L; Immunoglobulin A 1.73 g/L; Immunoglobulin M 0.27 g/L; Lactate Dehydrogenase 2.4 µkat/L; Hemoglobin 9.36 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 187 ×10⁹/L; Creatinine 99.9 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.35 mmol/L; Albumin 43 g/L; Total Protein 6.9 g/dL; Glucose 4.79 mmol/L.
- Day 625 (ECOG 1): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.15 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.83 mg/dL; Immunoglobulin G 11.7 g/L; Immunoglobulin A 1.51 g/L; Immunoglobulin M 0.27 g/L; Lactate Dehydrogenase 2.67 µkat/L; Hemoglobin 9.11 mmol/L; Leukocytes 5.7 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 222 ×10⁹/L; Creatinine 110 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.33 mmol/L; Albumin 39 g/L; Total Protein 6.6 g/dL; Glucose 5.17 mmol/L.
- Day 737 (ECOG 0): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.66 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.48 mg/dL; Immunoglobulin G 15.4 g/L; Immunoglobulin A 2.04 g/L; Immunoglobulin M 0.33 g/L; Lactate Dehydrogenase 2.63 µkat/L; Hemoglobin 9.86 mmol/L; Leukocytes 6.3 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 224 ×10⁹/L; Creatinine 110 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.48 mmol/L; Albumin 44 g/L; Total Protein 7.4 g/dL; Glucose 3.8 mmol/L.
- Day 821: M Protein 0.7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.45 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.79 mg/dL; Immunoglobulin G 19.1 g/L; Immunoglobulin A 2.43 g/L; Immunoglobulin M 0.4 g/L; Lactate Dehydrogenase 2.85 µkat/L; Hemoglobin 9.73 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 237 ×10⁹/L; Creatinine 99.9 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.35 mmol/L; Albumin 42 g/L; Total Protein 7.7 g/dL; Glucose 5.01 mmol/L.
- Day 914: M Protein 0.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.47 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.69 mg/dL; Immunoglobulin G 14.2 g/L; Immunoglobulin A 1.58 g/L; Immunoglobulin M 0.28 g/L; Lactate Dehydrogenase 2.18 µkat/L; Hemoglobin 9.18 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 191 ×10⁹/L; Creatinine 105 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.33 mmol/L; Albumin 39 g/L; Total Protein 6.8 g/dL; Glucose 6.38 mmol/L.
- Day 1,004: M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.92 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.46 mg/dL; Immunoglobulin G 9.58 g/L; Immunoglobulin A 0.85 g/L; Immunoglobulin M 0.18 g/L; Lactate Dehydrogenase 2.62 µkat/L; Hemoglobin 8.74 mmol/L; Leukocytes 5.9 ×10⁹/L; Absolute Neutrophil 3.7 ×10⁹/L; Platelets 168 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 9.28 mmol/L; Calcium 2.3 mmol/L; Albumin 38 g/L; Total Protein 6.1 g/dL; Glucose 5.5 mmol/L.
- Day 1,088 (ECOG 1): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.72 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.68 mg/dL; Immunoglobulin G 7.93 g/L; Immunoglobulin A 0.72 g/L; Immunoglobulin M 0.14 g/L; Lactate Dehydrogenase 4.35 µkat/L; Hemoglobin 8.93 mmol/L; Leukocytes 7.2 ×10⁹/L; Absolute Neutrophil 5.2 ×10⁹/L; Platelets 179 ×10⁹/L; Creatinine 94.6 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.35 mmol/L; Albumin 37 g/L; Total Protein 6.9 g/dL; Glucose 5.45 mmol/L.

Other clinical attributes
- Day 1: Weight: 93 kg; Height: 180 cm.

Family history
- Relative with cancer history: yes; Relationship type: Paternal Grandmother; Relationship sex at birth: female.
- Relative with cancer history: yes; Relationship type: Paternal Grandfather; Relationship primary diagnosis: Lung Cancer; Relationship sex at birth: male.

Biospecimens (2 samples)
- Sample MMRF_1825_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_1825_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
